Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A196, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A196-01A (Primary Tumor).

PATIENT HISTORY:

No clinical history is given.

PRE-OP DIAGNOSIS: Left leg melanoma.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Wide local excision of skin and SLNB and skin graft.

105-0-3
Melanoma, acral lentiginous, malignant8744/3 12/14/10
lw

Site Code: Skin of foot 044.7

FINAL DIAGNOSIS:**PART 1: SKIN, FOOT, LEFT, WIDE LOCAL EXCISION -**

- A. ULCERATED NODULAR MELANOMA, ACRAL LENTIGINOUS TYPE.
- B. CLARK LEVEL IV; 22 MM IN MAXIMUM THICKNESS.
- C. NO TUMOR INFILTRATING LYMPHOCYTES.
- D. MARGIN FREE OF TUMOR.
- E. NO ANGIOLYMPHATIC INVASION IDENTIFIED.
- F. POSSIBLE PERINEURAL INVASION SEEN.

PART 2: SENTINEL LYMPH NODE #1, GROIN, LEFT, BIOPSY -

LYMPH NODE, NEGATIVE FOR TUMOR CELLS. (see comment)

PART 3: SENTINEL LYMPH NODE #2, GROIN, LEFT, BIOPSY -

LYMPH NODE, NEGATIVE FOR TUMOR CELLS. (see comment)

PART 4: SENTINEL LYMPH NODE #3, GROIN, LEFT, BIOPSY -

LYMPH NODE, NEGATIVE FOR TUMOR CELLS.

PART 5: SENTINEL LYMPH NODE #4, GROIN, LEFT, BIOPSY -

LYMPH NODE, NEGATIVE FOR TUMOR CELLS.

PART 6: SENTINEL LYMPH NODE #1, POPLITEAL, LEFT, BIOPSY -

LYMPH NODE, NEGATIVE FOR TUMOR CELLS. (see comment)

**COMMENT:**

No tumor cells found on immunostains with HMB 45, S100, melan A, CD58, tyrosinase in groin sentinel lymph nodes in parts #1 and #2 and popliteal sentinel lymph node in part #6.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY CUTANEOUS MELANOMA**

TUMOR LOCATION:	Family history of melanoma is unknown.
TYPE OF PROCEDURE:	Family history of dysplastic nevi is unknown.
SIZE OF TUMOR:	Lower extremities
GROSS ULCERATION:	Wide excision
GROSS SATELLITES:	Maximum surface diameter of neoplasm: 66 mm
HISTOLOGIC TYPE:	Yes
SURFACE ULCERATION:	No
CLARK'S LEVEL:	Acral lentiginous
BRESLOW'S THICKNESS:	< 50%
ANGIOLYMPHATIC INVASION:	IV
PERINEURAL INVASION:	22 mm
EVIDENCE OF REGRESSION:	No
MICROSCOPIC SATELLITES:	Yes
PREEXISTING NEVUS:	No
TUMOR INFILTRATING LYMPHOID INFILTRATE:	No preexisting nevus
MITOTIC RATE:	None (absent)
VASCULARITY:	10 / 10 HPF
SURGICAL MARGIN INVOLVEMENT:	Not increased to focally increased
SENTINEL LYMPH NODE MAPPING:	Deep margin is free of tumor, Lateral margin is free of tumor
SENTINEL LYMPH NODE INVOLVEMENT:	Yes
	No
LYMPH NODES EXAMINED:	Number of sentinel lymph nodes positive: 0
COMPLETION DISSECTION:	Total number of lymph nodes examined: 5
EXTRACAPSULAR SPREAD:	No
T STAGE, PATHOLOGIC:	None
N STAGE, PATHOLOGIC:	pT4b
M STAGE, PATHOLOGIC:	pN0
	PMX

Source: NCI Genomic Data Commons file c30ee1b5-5dd2-4b4d-8a40-4dc04a441725 (TCGA-ER-A196.A80CD991-4AF1-4C22-8F05-EC4CA14D0828.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).